Somatic mutation profile of tumor specimen ALCH-B2T3-TTP1-B (aliquot ALCH-B2T3-TTP1-B-1-0-D-A83F-36) from ALCHEMIST case ALCH-B2T3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.1 years (26,350 days).
Specimen ALCH-B2T3-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe1bd28a-df25-4074-849d-05576ebc1558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T3-NB1-A (Blood Derived Normal), aliquot ALCH-B2T3-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb43ed02-ab91-4801-921c-cc6975d007ac

The open-access MAF lists 346 somatic variants for this specimen: 213 protein-altering or splice-affecting, 82 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 189, Silent 82, Intron 23, Nonsense Mutation 15, 5'UTR 8, RNA 7, 3'UTR 6, Splice Site 4, 5'Flank 4, Frame Shift Del 3, 3'Flank 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as rs1555401667, CM152325; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 27/199 reads (14%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.3992G>C p.R1331T | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV52644527, COSV99446466; called by muse, mutect2
- ACAD11 | c.1936G>T p.A646S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.439); catalogued as COSV53900897; called by muse, mutect2, varscan2
- ACTR3C | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52738811; called by muse, mutect2, varscan2
- ANGPTL8 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs1462580717; called by muse, mutect2
- BEND2 | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.044); catalogued as COSV66217566; called by muse, mutect2, varscan2
- CARF | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.385); catalogued as COSV57547067; called by muse, mutect2
- CCDC66 | c.328G>C p.E110Q (on ENST00000394672 / NM_001353147.1; = p.E76Q on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV58302725; called by muse, mutect2
- CCND2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV54226910; called by muse, mutect2, varscan2
- CD93 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as COSV55669140; called by muse, mutect2
- CLEC1A | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59532942; called by muse, mutect2
- CLSTN3 | c.746G>A p.W249* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV56940024; called by muse, mutect2, varscan2
- CNGB3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 35/504 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as rs1020619170, COSV100182499; called by muse, mutect2
- COL1A2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.334); catalogued as rs1468386859, COSV51962597; called by muse, mutect2, varscan2
- CRYL1 | c.921G>C p.M307I | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV104402836; called by muse, mutect2, varscan2
- CUBN | c.2566C>T p.L856F | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV64713927; called by muse, mutect2
- CYP2D7 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs775086719, COSV63852615; called by muse, mutect2, varscan2
- DNAH7 | c.4702G>C p.D1568H | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56758034; called by muse, mutect2, varscan2
- DPYD | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs757695236; called by muse, mutect2, varscan2
- DSPP | c.1551C>A p.S517R | Missense Mutation (SNP) | VAF 64/711 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.743); catalogued as COSV56816884; called by muse, mutect2
- E2F8 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as COSV51462992; called by muse, mutect2
- EIF4G3 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV51685309; called by muse, mutect2
- EPS8 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55537428; called by muse, mutect2
- FAM83A | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs548147359; called by muse, mutect2, varscan2
- FIG4 | c.2293G>C p.D765H | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100020252; called by muse, mutect2, varscan2
- FLG | c.11741A>C p.Q3914P | Missense Mutation (SNP) | VAF 83/649 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs193139392; called by muse, mutect2, varscan2
- FOXN4 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs1384493981; called by muse, mutect2, varscan2
- GBA | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV100516368, COSV59169753; called by muse, mutect2
- GRM5 | c.2882T>A p.L961Q (on ENST00000305447 / NM_001143831.2; = p.L929Q on NM_000842.4) | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1202058113; called by muse, mutect2, varscan2
- HAVCR2 | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV57153829; called by muse, mutect2, varscan2
- HK2 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.217); catalogued as rs139442407; called by muse, mutect2, varscan2
- HSP90AB1 | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs559392885, COSV99240880; called by muse, mutect2, varscan2
- HTR3B | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52746435; called by muse, mutect2
- IGHV3-33 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 41/475 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777178681; called by muse, mutect2
- IQCF2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs756576003; called by muse, mutect2, varscan2
- ITPR2 | c.6553G>C p.E2185Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101190161; called by muse, mutect2
- JARID2 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100521874; called by muse, mutect2, varscan2
- KCNA10 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768535829, COSV63904462; called by muse, mutect2, varscan2
- KCNJ8 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs768851540; called by muse, mutect2, varscan2
- KCNK13 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99030217; called by muse, mutect2, varscan2
- KIF23 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52980185; called by muse, mutect2, varscan2
- KIR2DL3 | c.318C>G p.H106Q | Missense Mutation (SNP) | VAF 20/310 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs753571262; called by muse, mutect2
- KRT75 | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 112/367 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV99359156; called by muse, mutect2, varscan2
- MAP7D2 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1333753597; called by muse, mutect2, varscan2
- MITF | c.1294C>T p.H432Y (on ENST00000448226 / NM_006722.3; = p.H332Y on NM_000248.4) | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.15); catalogued as COSV58830869; called by muse, mutect2, varscan2
- MRGPRX4 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs376982271; called by muse, mutect2
- MYH9 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53382609; called by muse, mutect2
- NFE2L3 | c.1730C>G p.S577* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV50230253; called by muse, mutect2, varscan2
- NGLY1 | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV54989139; called by muse, mutect2, varscan2
- NTF4 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1220929905, COSV100032250; called by muse, mutect2, varscan2
- OLFML2A | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 24/257 reads (9%) | catalogued as COSV99992602; called by muse, mutect2
- OR2T1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs756402494, COSV63541543; called by muse, mutect2
- OR51A7 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs753338342, COSV63788015; called by muse, mutect2, varscan2
- OR52A1 | c.84G>C p.W28C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV61092095; called by muse, mutect2, varscan2
- OTOG | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448595162; called by muse, mutect2
- OTUD7A | c.922G>A p.E308K (on ENST00000307050 / NM_001382637.1; = p.E301K on NM_130901.3) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs754202329, COSV61044183; called by muse, mutect2
- PCDH9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.696); catalogued as COSV100119593, COSV60583607; called by muse, mutect2, varscan2
- PCDHB4 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV52026165; called by muse, mutect2, varscan2
- PDGFRL | c.662C>G p.T221R | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs145072413; called by muse, mutect2
- PPP1R12A | c.1670G>C p.R557T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV54107781; called by muse, mutect2
- PRKAR2B | c.1243G>C p.E415Q | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55924926; called by muse, mutect2, varscan2
- PTPN4 | c.1356-1G>A p.X452_splice | Splice Site (SNP) | VAF 12/122 reads (10%) | catalogued as COSV55297266; called by muse, mutect2
- PTPRR | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as COSV51727574; called by muse, mutect2
- RASGRP2 | c.72C>T p.F24= | Splice Region (SNP) | VAF 35/360 reads (10%) | catalogued as COSV99377666; called by muse, mutect2
- RICTOR | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV99704448; called by muse, mutect2, varscan2
- RNF10 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.121); catalogued as rs760265294; called by muse, mutect2
- RNF43 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs757680292, COSV68456879, COSV68457530; called by muse, mutect2, varscan2
- RTL1 | c.3790G>A p.V1264M | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.874); catalogued as rs765524569, COSV101128220; called by muse, mutect2, varscan2
- RUNX1 | c.425G>C p.R142T (on ENST00000344691 / NM_001001890.3; = p.R169T on NM_001754.5) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55870785; called by muse, mutect2
- SEL1L | c.2267G>A p.G756E | Missense Mutation (SNP) | VAF 41/284 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs756594983; called by muse, mutect2, varscan2
- SESN2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV99455474; called by muse, mutect2
- SNX1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.531); catalogued as rs758734208; called by muse, mutect2, varscan2
- SOGA3 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs371373846; called by muse, mutect2, varscan2
- SOX2 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100327199; called by muse, mutect2
- SPAG9 | c.2836G>A p.D946N (on ENST00000262013 / NM_001130528.3; = p.D932N on NM_003971.6) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1202769720; called by muse, mutect2
- SPTLC3 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV100983153; called by muse, mutect2, varscan2
- TMEM67 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV60040811; called by muse, mutect2
- TNPO2 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV63509477; called by muse, mutect2
- TRIM26 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.738); catalogued as rs147887830; called by muse, mutect2
- TRIM31 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs1562051569; called by muse, mutect2
- TRIM48 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 13/306 reads (4%) | catalogued as COSV70162502; called by muse, mutect2
- UGT2A2 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as COSV54138445, COSV54145273; called by muse, mutect2, varscan2
- USP34 | c.10148C>G p.T3383R | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.423); catalogued as rs547690935; called by muse, mutect2, varscan2
- USP42 | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.127); catalogued as rs1423525359; called by muse, mutect2, varscan2
- XKR4 | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59332084; called by muse, mutect2, varscan2
- ZBED6CL | c.8T>G p.V3G | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1343463201; called by muse, mutect2
- ZBTB33 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs376833183, COSV58532954; called by muse, mutect2, varscan2
- ZNF557 | c.949G>A p.D317N (on ENST00000414706 / NM_001044388.2; = p.D324N on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs372175928; called by mutect2, varscan2
- ZSCAN5B | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.996); catalogued as rs1422845249, COSV61999169; called by muse, mutect2, varscan2
- ACADL | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ADA | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 37/502 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.332); called by muse, mutect2
- ADAMTS19 | c.1800G>C p.K600N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ADGRA3 | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2
- AHNAK | c.6433G>A p.D2145N | Missense Mutation (SNP) | VAF 27/390 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2
- AIMP1 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- ALG10 | c.1228C>G p.Q410E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- AMH | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.096); called by muse, mutect2
- ANKRD26 | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- ANKRD45 | c.797del p.N266Tfs*37 | Frame Shift Del (DEL) | VAF 29/202 reads (14%) | called by mutect2, pindel, varscan2
- ANKS6 | c.863-1G>A p.X288_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- AQR | c.3781G>C p.D1261H | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- BCAT1 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIN2 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.051); called by muse, mutect2
- C1GALT1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C2orf42 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- C6orf52 | c.347C>G p.S116* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- CACNA1D | c.3847G>C p.D1283H (on ENST00000350061 / NM_001128840.3; = p.D1303H on NM_000720.4) | Missense Mutation (SNP) | VAF 30/437 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CASP5 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2
- CCAR1 | c.3283G>C p.E1095Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- CCDC87 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CD5L | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDKN2C | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.04); called by muse, mutect2
- CEP152 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CHAF1A | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNKSR1 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- COL6A6 | c.4533+7G>A | Splice Region (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- CSRNP3 | c.408+2del p.X136_splice | Splice Site (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel, varscan2
- CYP27B1 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 46/643 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.104); called by muse, mutect2
- DENND2B | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- DGCR8 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.465); called by muse, varscan2
- DISC1 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- DNAH8 | c.2200C>G p.L734V | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- DNAJC22 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DUSP10 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- DYNC2H1 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2
- EARS2 | c.147G>T p.L49F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EPHA3 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, varscan2
- ETV3 | c.1439G>A p.W480* | Nonsense Mutation (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- FAM214B | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCGR2C | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 57/290 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- FERMT3 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FLVCR2 | c.1518_1521del p.E507Rfs*49 | Frame Shift Del (DEL) | VAF 32/308 reads (10%) | called by pindel, varscan2
- FOXL3 | c.73G>C p.D25H | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2
- FTO | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GALE | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GAS1 | c.568T>A p.C190S | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- GLUD1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.5952G>T p.Q1984H (on ENST00000467148 / NM_001037335.2; = p.Q1415H on NM_033405.3) | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- HHIPL2 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- HIP1 | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- HSPA1L | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- HSPG2 | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- IGLV3-12 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2
- KLHL1 | c.1952C>T p.A651V | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.498); called by muse, mutect2
- KLHL4 | c.1629G>T p.W543C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KPRP | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- KRI1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- LIN7A | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEB16 | c.92C>A p.S31Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MAML3 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP6 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MAT2A | c.654G>C p.M218I | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2
- MDGA2 | c.2336C>T p.P779L (on ENST00000399232 / NM_001113498.2; = p.P481L on NM_182830.4) | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MROH1 | c.2164C>G p.L722V | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MRPL17 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MYADML2 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- MYH9 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 24/496 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2
- NAALADL2 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NEFH | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- NET1 | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- NPEPPS | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- NPY5R | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OR2L2 | c.827T>C p.F276S | Missense Mutation (SNP) | VAF 43/226 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- OR52W1 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2
- P2RY2 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- PDF | c.519G>C p.E173D | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PER2 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2
- PHLDB2 | c.2444C>G p.S815C (on ENST00000393925 / NM_001134439.2; = p.S772C on NM_145753.2) | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PODXL2 | c.1658C>T p.T553M | Missense Mutation (SNP) | VAF 57/216 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R3E | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRRC2B | c.5408C>T p.S1803F | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- PRUNE2 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); called by muse, mutect2
- PTBP2 | c.1502A>G p.K501R (on ENST00000426398 / NM_001300986.2; = p.K492R on NM_021190.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PTN | c.139T>A p.C47S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRB | c.4400C>G p.S1467C | Missense Mutation (SNP) | VAF 132/719 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBM14 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2
- RBM6 | c.3315G>C p.E1105D | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RFC1 | c.3311C>T p.S1104F (on ENST00000381897 / NM_001363496.2; = p.S1103F on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.303); called by muse, mutect2
- RGS13 | c.-4-1G>C | Splice Site (SNP) | VAF 11/91 reads (12%) | called by muse, mutect2, varscan2
- RNF44 | c.969C>G p.I323M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- RYR2 | c.1111T>G p.W371G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SAMM50 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN11A | c.1523A>G p.D508G | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SCN7A | c.2705G>A p.R902K | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- SLC7A3 | c.752A>T p.E251V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SLFN12L | c.1287del p.W429Cfs*19 (on ENST00000260908 / NM_001363830.1; = p.W447Cfs*19 on NM_001195790.1) | Frame Shift Del (DEL) | VAF 25/211 reads (12%) | called by mutect2, pindel, varscan2
- SMAD1 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- SMOC2 | c.748C>T p.Q250* (on ENST00000356284 / NM_001166412.2; = p.Q261* on NM_022138.3) | Nonsense Mutation (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- SORCS1 | c.3370A>G p.R1124G | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- SOS1 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); called by muse, varscan2
- SPATA16 | c.282A>C p.R94S | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2
- SREBF2 | c.3011C>T p.S1004L | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2
- SYAP1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SYCN | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.154); called by mutect2, varscan2
- TACC3 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TAOK1 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- TICAM1 | c.1573G>T p.A525S | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2
- TICRR | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2
- TIGD1 | c.1411C>G p.L471V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.364); called by muse, mutect2
- TRMO | c.872G>C p.R291T | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TSEN54 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TSEN54 | c.1272C>G p.I424M | Missense Mutation (SNP) | VAF 30/499 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TTLL6 | c.1253A>G p.D418G (on ENST00000393382 / NM_001130918.3; = p.D111G on NM_173623.3) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBR4 | c.9460G>A p.E3154K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2
- UNK | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- VIPAS39 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.137); called by muse, mutect2
- YIPF7 | c.731T>A p.L244H | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2
- ZBTB11 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2
- ZNF326 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF429 | c.1505T>A p.I502N | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF530 | c.947T>G p.V316G | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ZNF705A | c.640C>G p.H214D | Missense Mutation (SNP) | VAF 22/243 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA8 | c.1776A>G p.E592= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs772649172; called by muse, mutect2, varscan2
- ABCG4 | c.1218C>T p.I406= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as rs145578285; called by muse, mutect2, varscan2
- ACSL4 | c.675C>T p.I225= (on ENST00000340800 / NM_022977.2; = p.I184= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100538283, COSV100538680; called by muse, mutect2, varscan2
- ADAMTS4 | c.759C>T p.F253= | Silent (SNP) | VAF 67/313 reads (21%) | called by muse, mutect2, varscan2
- ADGRF3 | c.1383G>A p.V461= (on ENST00000311519 / NM_001145168.1; = p.V262= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- AKAP13 | c.6333C>T p.F2111= (on ENST00000394518 / NM_007200.5; = p.F2115= on NM_006738.6) | Silent (SNP) | VAF 13/173 reads (8%) | called by muse, mutect2
- ALPP | c.984C>T p.F328= | Silent (SNP) | VAF 46/356 reads (13%) | catalogued as COSV67396822; called by muse, mutect2, varscan2
- ARHGAP4 | c.639C>G p.L213= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- ARSH | c.538C>T p.L180= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as COSV66963509; called by muse, mutect2, varscan2
- ASCC2 | c.1290C>T p.V430= | Silent (SNP) | VAF 12/167 reads (7%) | catalogued as rs912358346; called by muse, mutect2
- BAIAP2L2 | c.576G>T p.L192= | Silent (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- BAIAP3 | c.3198G>A p.Q1066= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- BRD1 | c.2562C>G p.S854= (on ENST00000216267 / NM_001349940.1; = p.S985= on NM_001304808.3) | Silent (SNP) | VAF 26/263 reads (10%) | called by muse, mutect2
- C2CD2 | c.636C>G p.L212= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as rs527948043; called by muse, mutect2
- CDC20B | c.1132C>T p.L378= | Silent (SNP) | VAF 27/319 reads (8%) | catalogued as rs1053361039; called by muse, mutect2
- CFAP97 | c.1152G>C p.V384= | Silent (SNP) | VAF 16/198 reads (8%) | called by muse, mutect2
- CHERP | c.417G>A p.V139= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as rs1397466892; called by muse, mutect2
- CLTC | c.3690C>T p.T1230= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs1567970377; called by muse, mutect2
- CSF3R | c.1692C>T p.I564= | Silent (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- CYP2A7 | c.57C>G p.V19= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV52498776; called by muse, mutect2
- E2F8 | c.2181G>A p.Q727= | Silent (SNP) | VAF 35/254 reads (14%) | called by muse, mutect2, varscan2
- EGFR | c.2991C>T p.F997= | Silent (SNP) | VAF 13/282 reads (5%) | catalogued as COSV51837327, COSV51840483; called by muse, mutect2
- EPHA6 | c.1575C>T p.F525= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- ERFE | c.501C>T p.L167= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs1050871300; called by muse, mutect2, varscan2
- ESR2 | c.816C>G p.L272= | Silent (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- EVI5L | c.1407G>T p.L469= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- EXTL3 | c.2676C>T p.L892= | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- FBXO45 | c.696C>A p.V232= | Silent (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- FBXO6 | c.75C>T p.F25= | Silent (SNP) | VAF 17/236 reads (7%) | called by muse, mutect2
- FETUB | c.756G>A p.V252= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as COSV54006390; called by muse, mutect2
- FSIP2 | c.5307C>G p.L1769= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- GLTPD2 | c.783G>A p.R261= | Silent (SNP) | VAF 11/112 reads (10%) | catalogued as rs1226821543; called by muse, mutect2, varscan2
- GON4L | c.6609C>T p.L2203= | Silent (SNP) | VAF 22/373 reads (6%) | called by muse, mutect2
- HEATR1 | c.5478C>T p.I1826= | Silent (SNP) | VAF 26/270 reads (10%) | catalogued as rs1321575037, COSV63981884; called by muse, mutect2
- HNF4A | c.879C>A p.I293= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as COSV57379387; called by muse, mutect2
- INPP5J | c.1956C>G p.L652= (on ENST00000331075 / NM_001284285.2; = p.L284= on NM_001002837.2) | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- IPO13 | c.579C>T p.S193= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- ITGB5 | c.267G>C p.L89= | Silent (SNP) | VAF 32/278 reads (12%) | called by muse, mutect2, varscan2
- ITK | c.1135C>T p.L379= | Silent (SNP) | VAF 40/356 reads (11%) | catalogued as rs1184590044, COSV70060690; called by muse, varscan2
- KCNJ9 | c.741C>T p.I247= | Silent (SNP) | VAF 16/174 reads (9%) | called by muse, mutect2
- KIAA0100 | c.1053C>G p.V351= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV66491120; called by muse, mutect2, varscan2
- KRT81 | c.189C>T p.F63= | Silent (SNP) | VAF 15/244 reads (6%) | called by muse, varscan2
- LAMA3 | c.9801G>A p.Q3267= (on ENST00000313654 / NM_198129.4; = p.Q1658= on NM_000227.6) | Silent (SNP) | VAF 53/271 reads (20%) | catalogued as rs1461089698, COSV52543805; called by muse, mutect2, varscan2
- LIMK2 | c.819G>A p.E273= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV59183385; called by muse, mutect2, varscan2
- MAF1 | c.282C>T p.F94= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as rs1302463132; called by muse, mutect2
- MYH7 | c.4131G>A p.T1377= | Silent (SNP) | VAF 43/516 reads (8%) | catalogued as rs369420587; ClinVar: likely benign; called by muse, mutect2
- MYOT | c.549G>A p.E183= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as rs1257349872; called by muse, mutect2
- NDUFA4 | c.117C>T p.F39= | Silent (SNP) | VAF 25/235 reads (11%) | called by muse, mutect2, varscan2
- PDP1 | c.96C>G p.L32= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- POT1 | c.288C>T p.I96= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- PRSS21 | c.768G>C p.V256= | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- RASAL2 | c.1146C>G p.L382= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs765301486, COSV62719670; called by muse, mutect2, varscan2
- RBMXL3 | c.2478C>T p.L826= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs1272594214; called by muse, mutect2, varscan2
- RGS14 | c.351G>A p.E117= | Silent (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- RGS5 | c.39G>A p.L13= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as rs765944943; called by muse, varscan2
- RPLP0 | c.429C>T p.I143= | Silent (SNP) | VAF 13/126 reads (10%) | catalogued as rs553386311, COSV56107650; called by muse, mutect2, varscan2
- RPN1 | c.402C>G p.V134= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- RTL5 | c.1176G>A p.E392= | Silent (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- SCAMP3 | c.537C>G p.L179= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- SHOX2 | c.456C>T p.L152= (on ENST00000441443 / NM_006884.3; = p.L176= on NM_003030.4) | Silent (SNP) | VAF 47/422 reads (11%) | called by muse, mutect2, varscan2
- SIRPG | c.114G>A p.E38= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV99403972; called by muse, mutect2
- SLC20A2 | c.861C>T p.L287= | Silent (SNP) | VAF 31/360 reads (9%) | catalogued as rs1339636964; called by muse, mutect2
- SLC25A40 | c.957T>C p.S319= | Silent (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- SLN | c.30C>T p.L10= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- SMIM1 | c.195C>T p.I65= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- SNN | c.177C>T p.P59= | Silent (SNP) | VAF 13/148 reads (9%) | called by muse, mutect2
- SPTA1 | c.766A>C p.R256= | Silent (SNP) | VAF 68/380 reads (18%) | called by muse, mutect2, varscan2
- SYNPO2L | c.978C>T p.G326= (on ENST00000394810 / NM_001114133.3; = p.G102= on NM_024875.5) | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- TMEM132B | c.1458G>A p.G486= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- TRBV20OR9-2 | c.372C>T p.F124= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- TRPC5 | c.2121G>A p.L707= | Silent (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- TUBB8 | c.243C>T p.F81= | Silent (SNP) | VAF 19/321 reads (6%) | catalogued as rs782384848, COSV59115518; called by muse, mutect2
- TUBB8B | c.243C>T p.F81= | Silent (SNP) | VAF 25/305 reads (8%) | catalogued as rs547575993; called by muse, mutect2
- UCK2 | c.345C>G p.V115= | Silent (SNP) | VAF 19/192 reads (10%) | called by muse, mutect2
- UTP14C | c.1395G>A p.L465= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1260884272; called by muse, mutect2
- WDR91 | c.1821C>G p.V607= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2, varscan2
- WNT9B | c.447G>A p.P149= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as rs139153567; called by muse, mutect2
- YIPF5 | c.363C>T p.I121= | Silent (SNP) | VAF 13/178 reads (7%) | called by muse, mutect2
- ZNF107 | c.897C>G p.L299= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100788562; called by muse, mutect2
- ZNF385C | c.1200G>T p.L400= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- ZNF521 | c.159C>T p.L53= | Silent (SNP) | VAF 10/172 reads (6%) | called by muse, mutect2
- ZNF565 | c.231G>A p.E77= (on ENST00000355114; = p.E37= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- AC073648.1 | n.682A>T | RNA (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2
- AC124067.3 | n.175G>A | RNA (SNP) | VAF 13/136 reads (10%) | catalogued as rs1369925432; called by muse, mutect2, varscan2
- AFF3 | chr2:100105640 C>T | 5'Flank (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- AK2 | c.*329G>A | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- AKR1E2 | c.838-1338C>T | Intron (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- AL359195.2 | n.3441C>G | RNA (SNP) | VAF 14/97 reads (14%) | catalogued as rs1206381863; called by muse, mutect2
- AP000769.5 | chr11:65499359 del AGAA | 5'Flank (DEL) | VAF 29/147 reads (20%) | catalogued as rs768335830; called by mutect2, pindel, varscan2
- ATP2B2 | chr3:10449544 G>A | 5'Flank (SNP) | VAF 36/402 reads (9%) | called by muse, mutect2
- CEP295 | chr11:93730615 C>T | 3'Flank (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- CSH1 | c.456+81T>A | Intron (SNP) | VAF 34/356 reads (10%) | called by muse, mutect2
- CYB5R3 | c.21+4840G>C | Intron (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- DYNC1H1 | c.11055+31C>G | Intron (SNP) | VAF 17/135 reads (13%) | called by muse, mutect2, varscan2
- FLT1 | c.1552-1991C>T | Intron (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- FRMPD4 | c.-27C>T | 5'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101042178; called by muse, mutect2
- GCSAML | c.-56-10382G>A | Intron (SNP) | VAF 9/155 reads (6%) | called by muse, mutect2
- GRHL3 | c.1694+4343C>G | Intron (SNP) | VAF 34/157 reads (22%) | called by muse, mutect2, varscan2
- IGFBP3 | chr7:45921695 C>T | 5'Flank (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- IMPDH1 | c.-9C>G | 5'UTR (SNP) | VAF 8/210 reads (4%) | called by muse, mutect2
- JAKMIP1 | chr4:6049869 C>A | 3'Flank (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- LINC00840 | n.334G>T | RNA (SNP) | VAF 14/372 reads (4%) | called by muse, mutect2
- LMF1 | c.*2C>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | catalogued as rs372841884, COSV51893370; called by mutect2, varscan2
- MAGI1 | c.3635-1989G>A | Intron (SNP) | VAF 12/121 reads (10%) | catalogued as COSV58321253; called by muse, mutect2
- MORC2 | chr22:30922507 C>G | 3'Flank (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- MSRB2 | c.-11G>C | 5'UTR (SNP) | VAF 14/142 reads (10%) | catalogued as rs1239199199; called by muse, mutect2
- MVK | c.678-44C>G | Intron (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2, varscan2
- MYNN | c.1483+183G>C | Intron (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- NAMPTP1 | n.277C>A | RNA (SNP) | VAF 21/273 reads (8%) | catalogued as rs1488832326; called by muse, mutect2
- NLGN4Y | c.*1039G>C | 3'UTR (SNP) | VAF 16/196 reads (8%) | catalogued as rs914603689, COSV104410747; called by muse, mutect2
- OPRM1 | c.1164+1947G>A | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs200030378, COSV57685451; called by mutect2, varscan2
- PEX10 | c.113-349G>C | Intron (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- PFKM | c.238-9C>T | Intron (SNP) | VAF 11/210 reads (5%) | catalogued as rs1410090927; called by muse, mutect2
- PIGQ | c.1532-720C>T | Intron (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- RBMY2FP | n.433C>T | RNA (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- RECQL4 | c.85-31G>A | Intron (SNP) | VAF 9/74 reads (12%) | called by muse, varscan2
- RNF34 | c.-36C>A | 5'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- RTF2 | c.70-888G>C | Intron (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- RUNX2 | c.-38G>C | 5'UTR (SNP) | VAF 23/210 reads (11%) | called by muse, mutect2, varscan2
- SARNP | c.406+60A>G | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- SHOC2 | c.-235+17108C>G | Intron (SNP) | VAF 18/449 reads (4%) | called by muse, mutect2
- SIX4 | c.-215T>A | 5'UTR (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- SLC26A8 | c.-71G>T | 5'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- SPATA31D5P | n.965G>C | RNA (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- SYT14 | c.*671C>T | 3'UTR (SNP) | VAF 21/220 reads (10%) | catalogued as rs370999226; called by muse, mutect2
- TTC39A | c.999+252G>C | Intron (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- UBE2B | c.330+637C>G | Intron (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- UGT1A6 | c.862-23180C>T | Intron (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- UMPS | c.*3057G>A | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- ZNF419 | c.72+18C>T | Intron (SNP) | VAF 13/115 reads (11%) | catalogued as rs764175296; called by muse, mutect2, varscan2
- ZNF589 | c.-30C>T | 5'UTR (SNP) | VAF 27/245 reads (11%) | catalogued as rs1416869767; called by muse, mutect2
- ZNF672 | c.*374C>G | 3'UTR (SNP) | VAF 22/486 reads (5%) | catalogued as rs1441029773; called by muse, mutect2
- ZNF678 | c.-164+18825G>C | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
